Surgical pathology report (de-identified scan), TCGA case TCGA-VF-A8AE, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Pennsylvania, specimen TCGA-VF-A8AE-01A (Primary Tumor).

[page 1 of 3]
Panel: Surgical Pathology Final Report

Date: (

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-In progress/incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk (*) in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Collected	Value	Units	Range	Note
-------	-------------	-----------	-------	-------	-------	------

Surgical Pathology Final Report
Collection d/t:

Obs d/t:

Ordered by:

Surgical Pathology Report

ICD-O-3
Seminoma NOS 9061/3
Site: Ovary NOS C62.9
9/5/30/14

Final Diagnosis

1. Testis, right, radical orchiectomy:
- Classic seminoma, measuring 6.2 cm in maximum dimension.
- The tunica albuginea and vaginalis are free of involvement.
- The tumor involves the rete testis.
- No lymphovascular invasion is identified.
- Spermatic cord and spermatic cord margin, free of involvement.
- Intratubular germ cell neoplasia present.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Note

Extensive carry over artifact is noted on the testicular surface and vascular spaces.

No definitive lymphovascular invasion is present.

Synoptic Report

1: Testis, Radical Orchiectomy Summary

SERUM TUMOR MARKERS:

Serum marker studies within normal limits

SPECIMEN LATERALITY:

Right

TUMOR FOCALITY:

Unifocal

[page 2 of 3]
TUMOR SIZE:

Greatest dimension of main tumor mass: 6.2 cm

Additional dimensions: 5.0 x 3.0 cm

MACROSCOPIC EXTENT OF TUMOR:

Invades hilar soft tissues

The tumor involves the rete testis

HISTOLOGIC TYPE:

Seminoma, classic type

SPERMATIC CORD MARGIN:

Uninvolved by tumor

OTHER MARGIN(S):

Uninvolved by tumor: peripheral inked margins

MICROSCOPIC TUMOR EXTENSION:

Rete testis

LYMPH-VASCULAR INVASION:

Absent

PRIMARY TUMOR (pT):

pT1: Tumor limited to the testis and epididymis without vascular/lymphatic invasion; tumor may invade tunica albuginea but not tunica vaginalis

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

SERUM TUMOR MARKER(S):

S0: Serum marker study levels within normal limits

ADDITIONAL PATHOLOGIC FINDINGS:

Intratubular germ cell neoplasia

Pathologist(s)

Gross Description

The case is received in one fresh container, labeled with the patient's name and medical record number.

Specimen 1 is designated "right testicle" and consists of an intact testicle and spermatic cord. The testicle measures 6.5 x 5.5 x 3.4 cm, the spermatic cord measures 7.0 x 1.8 x 1.7 cm, and the epididymis measures 5.0 x 3.0 x 2.0 cm. The specimen weighs 89.3 g. The surface of the testicle is smooth and intact. The outer surface of the specimen is inked entirely in black. The testicle is bisected to reveal that the majority of the testicle has been taken over by a mass which is heterogeneous. Portions of this mass appear hemorrhagic while the majority of this mass appears tan-pink and homogeneous. The mass measures 6.2 x 5.0 x 3.0 cm. On further serial sectioning the mass appears to have additional areas of grossly apparent hemorrhage but no necrosis. There is no residual tan-red testicular parenchyma identified. The mass appears to involve the entirety

[page 3 of 3]
of the testis; however, it does not appear to grossly invade the epididymis nor does it appear to grossly penetrate the tunica albuginea. The spermatic cord is serially sectioned and is grossly unremarkable.

A section of normal tissue and tumor has been frozen for research for

Representative sections are submitted as follows:

- 1A: Shave of resection margin of spermatic cord
- 1B: Representative section through mid section of spermatic cord
- 1C: Representative section through peri-testicular region of spermatic cord
- 1D-1K: Representative sections of the mass including areas of the epidermis and rete testis

SUMMARY OF SECTIONS: 11, multiple, representative

Dictated by:

Clinical Information

year-old with right testicular pain and swelling. Ultrasound today concerning for tumor.

Previous biopsy: No

Previous chemotherapy: No

Previous radiation: No

Pre-Operative Diagnosis: Not specified

Post-Operative Diagnosis: Not specified

Operation: Right radical orchiectomy

Specific questions to be answered: None

Specimen:

1. Right Testis, Tumor

*** End of report ***

Dual/Synchronous Primary, Noted		✓

Source: NCI Genomic Data Commons file 2c228db6-b45d-406e-b3ed-f9716336f739 (TCGA-VF-A8AE.AB805FAE-D59C-4420-A868-9B883990DF7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).